Surgical pathology report (de-identified scan), TCGA case TCGA-AA-3870, project TCGA-COAD (Colon Adenocarcinoma), tissue source site Indivumed, specimen TCGA-AA-3870-01A (Primary Tumor).

Diagnosis

1. Right hemicolectomy preparation with an ulcerated colon carcinoma characterized histologically as a poorly differentiated colorectal adenocarcinoma, located 1 cm from Bauhin's valve, encircling the intestinal wall at a length of 4.5 cm. Invasive spreading of the tumor within all intestinal wall layers to the level of the subserosa and to the mesocolic fatty tissue. Lymphangial branches in the area of the tumor margin. The peritoneum of the mesocolon displays small-nodular metastasis of the colon carcinoma.

Colon mucous membrane otherwise with a tubulovillous adenoma with moderate epithelial dysplasia (synonym: mild intraepithelial neoplasia). Ileum with evidence of a chronic mechanical ileus. Appendix with postinflammatory fibrosis and fibroid lumen obturation in the apical area. Oral and aboral resection margin as well as greater omentum are tumor-free. Five of 23 local lymph nodes with extensive metastases of the colon carcinoma, partly transcending the lymph node capsules. In the mesenterium there is a clearly defined mesenchymal spindle cell tumor, measuring 0.5 cm.

2. Small nodular peritoneal metastasis of the colon carcinoma (roof of the bladder).

The tumor stage is therefore pT3 pN2 (5/23) L1, V0, M1 () G3 R0

Source: NCI Genomic Data Commons file edc1f4ea-72f7-4540-bba4-1310156cabf7 (TCGA-AA-3870.339C9AC5-FD05-4D30-BFA6-6138481C1B8A.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).